Somatic mutation profile of tumor specimen TCGA-EZ-7264-01A (aliquot TCGA-EZ-7264-01A-11D-2024-08) from TCGA case TCGA-EZ-7264, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.7 years (17,432 days).
Specimen TCGA-EZ-7264-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66d6495c-06c4-4bf8-ab02-cb9fa39fd1f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EZ-7264-10A (Blood Derived Normal), aliquot TCGA-EZ-7264-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c1d2c8a-c1b2-459b-a3a1-6603f09c0d5f

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS9 | c.2675A>G p.K892R | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV55783467; called by muse, mutect2
- ARHGEF4 | c.1897C>A p.Q633K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV58123963; called by muse, mutect2, varscan2
- ATXN1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs771709819, COSV55219737; called by muse, mutect2, varscan2
- CIC | c.4450T>G p.F1484V | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50596357; called by muse, mutect2, varscan2
- FUBP1 | c.1576G>C p.A526P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV53932792; called by muse, mutect2, varscan2
- GCNA | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs374341284, COSV65467235; called by muse, varscan2
- HK3 | c.1979T>C p.I660T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755957085, COSV52841385; called by muse, mutect2, varscan2
- HUWE1 | c.3973C>G p.L1325V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53350480; called by muse, mutect2, varscan2
- JMJD1C | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs753421740, COSV67863212; called by muse, mutect2, varscan2
- MYO15A | c.6989A>G p.D2330G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV52758667; called by muse, mutect2, varscan2
- OTOF | c.3374G>C p.G1125A (on ENST00000272371 / NM_194248.3; = p.G378A on NM_004802.4) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55506332; called by muse, mutect2, varscan2
- PCSK2 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs754614068, COSV52730710; called by muse, mutect2, varscan2
- PDZD7 | c.119C>T p.T40M | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1160650482, COSV56520228, COSV56520961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIMREG | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs11538170; called by muse, mutect2, varscan2
- PRMT5 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53546935; called by muse, mutect2, varscan2
- PRRC2B | c.2458A>G p.I820V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1200426295, COSV61938467; called by muse, mutect2, varscan2
- STOM | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54416977; called by muse, mutect2, varscan2
- UPRT | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64920305; called by muse, mutect2
- ZNF347 | c.2464G>A p.V822M | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs368225234; called by muse, mutect2, varscan2
- FUS | c.854_856del p.N285del | In Frame Del (DEL) | VAF 42/202 reads (21%) | called by pindel, varscan2
- ANKRD27 | c.2400T>C p.N800= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV60132691; called by muse, mutect2, varscan2
- APOB | c.5037G>A p.G1679= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV51939907; called by muse, mutect2, varscan2
- CFAP65 | c.453G>A p.L151= (on ENST00000341552 / NM_194302.4; = p.L86= on NM_152389.4) | Silent (SNP) | VAF 59/138 reads (43%) | catalogued as COSV55390687; called by muse, mutect2, varscan2
- CPS1 | c.2076C>T p.G692= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as COSV51813495; called by muse, mutect2, varscan2
- KLHL26 | c.1062G>A p.T354= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs773079823, COSV56317762; called by muse, mutect2, varscan2
- SLFN12 | c.1542G>A p.S514= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs150878441; called by muse, mutect2, varscan2
- THEMIS | c.1599A>G p.E533= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs370955905; called by muse, mutect2, varscan2
